MMRF case MMRF_1906 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c93b9815-3f76-48c6-8b6c-1ec2ee08825d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 911 days (2.5 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.2 years (28,215 days); ISS stage: III; Days to last known disease status: 911 days (2.5 years); Days to last follow up: 911 days (2.5 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 28 days; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 63 days; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days; Days to treatment end: 313 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 344 days; Days to treatment end: 772 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 421 days (1.2 years); Days to treatment end: 422 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 421 days (1.2 years); Days to treatment end: 772 days (2.1 years).
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 792 days (2.2 years); Days to treatment end: 876 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 792 days (2.2 years); Days to treatment end: 813 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 820 days (2.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 911.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 9.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 262 mg/dL; Immunoglobulin G 111 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 4.09 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 23 g/L; Total Protein 12 g/dL; Glucose 4.57 mmol/L.
- Day 92 (ECOG 1): M Protein 2.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.4 mg/dL; Immunoglobulin G 31.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 8.2 g/dL; Glucose 7.37 mmol/L.
- Day 168 (ECOG 1): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.18 mg/dL; Immunoglobulin G 24.8 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.27 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.65 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 6.22 mmol/L.
- Day 281: M Protein 1.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.86 mg/dL; Immunoglobulin G 22.6 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.
- Day 351 (ECOG 0): M Protein 2.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 41.1 mg/dL; Immunoglobulin G 36.5 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.22 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 8.2 g/dL; Glucose 6.55 mmol/L.
- Day 449 (ECOG 0): M Protein 4.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 92.6 mg/dL; Immunoglobulin G 61.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.65 mmol/L; Albumin 29 g/L; Total Protein 10.4 g/dL; Glucose 6.05 mmol/L.
- Day 533 (ECOG 0): M Protein 3.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 108 mg/dL; Hemoglobin 5.52 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.01 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 30 g/L; Total Protein 8.7 g/dL; Glucose 6.16 mmol/L.
- Day 617 (ECOG 0): M Protein 2.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.2 mg/dL; Immunoglobulin G 29.9 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.61 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 30 g/L; Total Protein 7 g/dL; Glucose 6.6 mmol/L.
- Day 729 (ECOG 0): M Protein 2.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 73 mg/dL; Immunoglobulin G 36.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 30 g/L; Total Protein 8 g/dL; Glucose 8.75 mmol/L.
- Day 785 (ECOG 0): M Protein 2.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.3 mg/dL; Immunoglobulin G 39.8 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 8.3 g/dL; Glucose 5.28 mmol/L.
- Day 876 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 9.81 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.18 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 8.58 mmol/L.

Other clinical attributes
- Day -4: Weight: 75 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1906_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1906_2_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
